MMRF case MMRF_1917 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/87e6abec-b58f-4b1c-acc5-7553e746efd2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.6 years (19,948 days); ISS stage: I; Days to last known disease status: 718 days (2.0 years); Days to last follow up: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 16 days; Days to treatment end: 303 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 44 days; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 329 days; Days to treatment end: 389 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 715 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 0): M Protein 8.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0585 mg/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3.08 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.93 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 9 g/dL; Glucose 4.51 mmol/L.
- Day 72 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.945 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.854 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.42 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 164 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.721 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.804 mg/dL; Immunoglobulin G 4.4 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 256 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.644 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.29 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 343 (ECOG 0): Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.34 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 431 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.888 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.872 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Albumin 51 g/L; Total Protein 6.8 g/dL; Glucose 6.22 mmol/L.
- Day 529 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.849 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 571 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.786 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 718 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.674 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 8.7 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -21: Weight: 128 kg; Height: 186 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1917_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_1917_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
